Somatic mutation profile of tumor specimen TCGA-19-1789-01A (aliquot TCGA-19-1789-01A-01W-0643-08) from TCGA case TCGA-19-1789, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.2 years (25,282 days).
Specimen TCGA-19-1789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3490d99f-2ffb-49b9-bffa-f1bbfdbdc199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1789-10A (Blood Derived Normal), aliquot TCGA-19-1789-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45ba29c4-93cb-4a31-9994-956f0e209f7c

The open-access MAF lists 70 somatic variants for this specimen: 46 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 23, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV50039873; called by muse, mutect2, varscan2
- AKTIP | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.217); catalogued as rs373752479; called by muse, mutect2, varscan2
- ALMS1 | c.6034C>A p.P2012T | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); catalogued as COSV100043996, COSV52522603; called by muse, varscan2
- AXDND1 | c.2091C>T p.H697= | Splice Region (SNP) | VAF 179/409 reads (44%) | catalogued as rs767651503, COSV62648840; called by muse, mutect2, varscan2
- BCLAF3 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 164/504 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61413189; called by muse, mutect2, varscan2
- CCDC62 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as rs759024777, COSV53437208; called by muse, mutect2, varscan2
- CD8B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs772468080, COSV58928598; called by muse, mutect2, varscan2
- CHD6 | c.2032A>G p.M678V | Missense Mutation (SNP) | VAF 225/731 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs765443609, COSV58562653; called by muse, mutect2, varscan2
- CNTNAP3 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs369395838; called by muse, varscan2
- CSGALNACT1 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 120/281 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV59983763; called by muse, mutect2, varscan2
- CXXC4 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67297029; called by muse, mutect2, varscan2
- EGFR | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 499/671 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV51850088; called by muse, mutect2, varscan2
- ERCC6L | c.3269G>T p.R1090I | Missense Mutation (SNP) | VAF 15/430 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1434421525, COSV100559003; called by muse, mutect2
- ESR1 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52784273, COSV52803005; called by muse, mutect2, varscan2
- GPR174 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as rs1333054510, COSV52133979; called by muse, mutect2
- HSD3B2 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs765748123, COSV65594095; called by muse, mutect2, varscan2
- IRX1 | c.1383C>G p.D461E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV57362613; called by muse, mutect2, varscan2
- KRT7 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100081631, COSV59333210; called by muse, mutect2, varscan2
- LPAR4 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.51); catalogued as COSV70913115, COSV70913491; called by muse, mutect2, varscan2
- LRP1 | c.9577G>A p.G3193S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54526868; called by muse, mutect2, varscan2
- LZTR1 | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53148508, COSV53151982; called by muse, mutect2, varscan2
- MANBAL | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV101009426; called by muse, varscan2
- MECP2 | c.1410C>A p.N470K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57657326; called by muse, mutect2, varscan2
- NLRP12 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776866944, COSV60743363; called by muse, mutect2, varscan2
- NLRP4 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.927); catalogued as rs746532356, COSV56716114; called by muse, mutect2, varscan2
- NONO | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV52136825; called by muse, mutect2, varscan2
- OR5D13 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62335492; called by muse, mutect2, varscan2
- OR5D13 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.14); catalogued as COSV62334336, COSV62335498; called by muse, mutect2, varscan2
- PCDHB7 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV50754635; called by muse, mutect2, varscan2
- PLAUR | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 173/505 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV55391740; called by muse, mutect2, varscan2
- PLEKHA1 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64570452; called by muse, mutect2, varscan2
- PSMG1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV59001435; called by muse, mutect2, varscan2
- SAP30 | c.479G>C p.R160T | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56635222; called by muse, mutect2, varscan2
- SLC2A13 | c.1607A>C p.Y536S | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55128806; called by muse, mutect2, varscan2
- ST18 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV52510382, COSV52513867; called by muse, mutect2, varscan2
- STX2 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as COSV99892416; called by muse, mutect2
- STXBP5L | c.1832+1G>A p.X611_splice | Splice Site (SNP) | VAF 83/174 reads (48%) | catalogued as COSV56536261; called by muse, mutect2, varscan2
- TIMM8A | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58123935; called by muse, mutect2, varscan2
- TMC5 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV66867367; called by muse, mutect2, varscan2
- TNN | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53436193; called by muse, mutect2, varscan2
- USP11 | c.1320G>T p.Q440H (on ENST00000218348; = p.Q397H on NM_001371072.1) | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV54472493, COSV54473191; called by muse, mutect2, varscan2
- VAV1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58386551; called by muse, mutect2, varscan2
- YY2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 141/332 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV63412555; called by muse, mutect2, varscan2
- ZNF594 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs951822445; called by muse, mutect2
- ZNF780B | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99665292; called by muse, mutect2, varscan2
- ADGRB2 | c.4671dup p.K1558Qfs*23 (on ENST00000373658 / NM_001364857.2; = p.K1557Qfs*23 on NM_001294335.2) | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | called by pindel, varscan2
- CCDC172 | c.87G>A p.S29= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs753812553, COSV60940557; called by muse, mutect2, varscan2
- COL5A3 | c.3009G>A p.V1003= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as COSV53419729; called by muse, mutect2, varscan2
- EMILIN2 | c.966C>A p.I322= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV54427838; called by muse, mutect2, varscan2
- FBXW12 | c.297G>A p.T99= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs147668968; called by muse, mutect2, varscan2
- FNDC3B | c.2679G>A p.P893= | Silent (SNP) | VAF 109/258 reads (42%) | catalogued as rs764625583, COSV61050247; called by muse, mutect2, varscan2
- GREM1 | c.156G>A p.Q52= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100277795; called by muse, mutect2, varscan2
- H2AC4 | c.192G>A p.L64= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV52517845; called by muse, varscan2
- HDAC8 | c.561C>T p.D187= | Silent (SNP) | VAF 145/388 reads (37%) | catalogued as rs931276707, COSV65240054; called by muse, mutect2, varscan2
- KRT25 | c.1008G>A p.A336= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as rs1459792230, COSV100379925, COSV56443491; called by muse, mutect2, varscan2
- LRIG3 | c.1731G>T p.G577= | Silent (SNP) | VAF 59/173 reads (34%) | catalogued as COSV57866533; called by muse, varscan2
- MAGI1 | c.798A>G p.T266= | Silent (SNP) | VAF 113/338 reads (33%) | catalogued as rs763338326, COSV58345715; called by muse, mutect2, varscan2
- MTCL1 | c.2517C>T p.L839= (on ENST00000306329 / NM_001378206.1; = p.L479= on NM_015210.4) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV60410641; called by muse, mutect2, varscan2
- NINL | c.2064G>A p.E688= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54009304; called by muse, mutect2, varscan2
- PCDH7 | c.1839C>T p.D613= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV62343797; called by muse, mutect2, varscan2
- PMCH | c.187C>T p.L63= | Silent (SNP) | VAF 107/237 reads (45%) | catalogued as COSV59676816; called by muse, mutect2, varscan2
- PRSS16 | c.822C>T p.P274= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100041893, COSV57917059; called by muse, mutect2, varscan2
- SIGLEC8 | c.996C>T p.N332= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as rs771076418, COSV58473511; called by muse, mutect2, varscan2
- SSTR4 | c.882C>T p.H294= | Silent (SNP) | VAF 67/248 reads (27%) | catalogued as COSV54800299; called by muse, mutect2
- SSX4 | c.126C>G p.S42= | Silent (SNP) | VAF 49/316 reads (16%) | called by muse, mutect2, varscan2
- TACR3 | c.273G>A p.A91= | Silent (SNP) | VAF 190/536 reads (35%) | catalogued as rs773303941, COSV59199757, COSV59207202; called by muse, varscan2
- TP53I13 | c.297C>T p.S99= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99837901; called by muse, mutect2
- TRPM2 | c.1026C>T p.N342= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs747609422, COSV55977381; called by muse, mutect2, varscan2
- ZMAT3 | c.294C>G p.L98= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV60995572; called by muse, mutect2, varscan2
- DKC1 | c.1260-167T>A | Intron (SNP) | VAF 135/362 reads (37%) | catalogued as COSV101053841; called by muse, mutect2, varscan2
